Gene-level copy-number profile of tumor specimen TCGA-HM-A6W2-01A from TCGA case TCGA-HM-A6W2, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 35.0 years (12,775 days).
Specimen TCGA-HM-A6W2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.08c9601e-983c-4fc3-960f-df202b944ae9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HM-A6W2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c67484f2-e3c4-4e7c-9539-96127acc594b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 5,595; copy number 2: 50,265; copy number 3: 1,298; copy number 4: 2,607; copy number 5: 7; copy number 6: 8; copy number 9: 2; copy number 13: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HM-A6W2-01A-21D-A33N-01): tumor purity 0.85, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,360,024–116,370,090, 1 gene: LSAMP-AS1.
- chr7:105,013,425–105,115,019, 3 genes: KMT2E-AS1, KMT2E, AC005070.3.
- chr10:87,751,512–87,971,930, 7 genes (within-gene range 0–2): ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3.
- chr13:50,081,843–50,906,856, 9 genes (within-gene range 0–1): AL137060.5, DLEU1, AL137060.6, RPL18P10, AL137060.1, AL137060.3, ST13P4, RPL34P26, AL158195.1.
- chr13:98,329,655–98,333,236, 1 gene: AL161896.1.
- chr16:12,081,237–12,095,307, 3 genes: RPS23P6, AC007601.1, AC007601.2.
- chr21:14,818,843–15,014,430, 2 genes (within-gene range 0–2): AF127577.4, LINC02246.
- chr21:14,918,534–14,947,096, 1 gene: AF127577.3.
- chr21:14,961,309–14,964,233, 1 gene: AF127577.1.
- chr22:28,794,555–29,057,488, 5 genes (within-gene range 0–2): XBP1, Z93930.2, Z93930.3, Z93930.1, ZNRF3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:172,039,578–172,523,475, 8 genes, copy number 5–9 (within-gene range 2–9): FNDC3B, RPS27AP8, RN7SL141P, AC092964.1, BZW1P1, GHSR, TNFSF10, AC007919.1.
- chr8:90,058,608–90,791,632, 8 genes, copy number 6 (within-gene range 3–6): CALB1, AC004083.1, LINC00534, RNA5SP273, LINC01030, TMEM64, AC106038.1, AC106038.2.

Autosomal genes at a single copy (total copy number 1): 5,593. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
